MMRF case MMRF_2257 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d1978fcd-fabc-4ce5-83bb-57a277777451

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.8 years (24,755 days); ISS stage: II; Days to last known disease status: 817 days (2.2 years); Days to last follow up: 817 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 53.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.817 mg/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 0.362 g/L; Immunoglobulin M 0.597 g/L; Beta 2 Microglobulin 3.07 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 8.96 mmol/L; Calcium 2.19 mmol/L; Albumin 26 g/L; Total Protein 4.78 g/dL; Glucose 5.01 mmol/L.
- Day 96 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.772 mg/dL; Immunoglobulin G 2.39 g/L; Immunoglobulin A 2.87 g/L; Immunoglobulin M 0.398 g/L; Beta 2 Microglobulin 4.78 µg/mL; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 387 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 7.96 mmol/L; Albumin 22.8 g/L; Total Protein 4.9 g/dL; Glucose 4.84 mmol/L.
- Day 194 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 5.35 g/L; Immunoglobulin A 0.355 g/L; Immunoglobulin M 0.355 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 135 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL.
- Day 294 (ECOG 0): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 5.17 g/L; Immunoglobulin A 0.284 g/L; Immunoglobulin M 0.542 g/L; Lactate Dehydrogenase 4 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 26.8 mmol/L; Calcium 2.45 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL.
- Day 369 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 5.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 5.76 g/L; Immunoglobulin A 0.281 g/L; Immunoglobulin M 0.564 g/L; Beta 2 Microglobulin 2.27 µg/mL; Hemoglobin 7.94 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.83 mmol/L; Calcium 2.29 mmol/L; Albumin 34.1 g/L; Total Protein 6.13 g/dL; Glucose 5.06 mmol/L.
- Day 453: M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.971 mg/dL; Immunoglobulin G 5.11 g/L; Immunoglobulin A 0.317 g/L; Immunoglobulin M 0.696 g/L; Beta 2 Microglobulin 2.4 µg/mL; Hemoglobin 7.38 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.28 mmol/L; Albumin 34.2 g/L; Total Protein 5.65 g/dL; Glucose 4.73 mmol/L.
- Day 551 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 9.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Immunoglobulin G 5.72 g/L; Immunoglobulin A 0.308 g/L; Immunoglobulin M 0.925 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 7.66 mmol/L; Calcium 2.27 mmol/L; Albumin 36.8 g/L; Total Protein 6.23 g/dL.
- Day 670 (ECOG 0): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 5.22 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.987 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 9.33 mmol/L; Calcium 2.41 mmol/L; Total Protein 5.9 g/dL.
- Day 817 (ECOG 0): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.905 mg/dL; Immunoglobulin G 4.97 g/L; Immunoglobulin A 0.241 g/L; Immunoglobulin M 0.822 g/L; Beta 2 Microglobulin 2.32 µg/mL; Hemoglobin 8.62 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.66 mmol/L; Calcium 2.31 mmol/L; Albumin 35.8 g/L; Total Protein 6.29 g/dL; Glucose 4.24 mmol/L.

Other clinical attributes
- Day -8: Weight: 85 kg; Height: 173 cm.

Biospecimens (2 samples)
- Sample MMRF_2257_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_2257_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
